Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041122-09A.1 (aliquot TARGET-15-SJMPAL041122-09A.1-01D) from TARGET case TARGET-15-SJMPAL041122, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.3 years (486 days).
Specimen TARGET-15-SJMPAL041122-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcd90e27-e0c1-4cbd-bc05-d20a73b25cf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041122-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041122-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb49cca0-a6f4-4d40-a6ba-f7b00f989887

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 3, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GFRA4 | c.754G>T p.G252W (on ENST00000319242 / NM_145762.3; = p.G222W on NM_022139.4) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99293987; called by muse, mutect2
- IRS1 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59335069; called by muse, mutect2
- MACROD2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs557866799, COSV54026962; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1125C>A p.C375* (on ENST00000374531 / NM_001037293.2; = p.C407* on NM_053016.6) | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV57114465; called by muse, mutect2
- SLC19A1 | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV60758694; called by muse, mutect2
- ADGRA3 | c.1372del p.M458Wfs*9 | Frame Shift Del (DEL) | VAF 64/128 reads (50%) | called by mutect2, varscan2
- GPR162 | c.899C>A p.S300* (on ENST00000311268 / NM_019858.2; = p.S16* on NM_014449.2) | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- HDX | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PCNX1 | c.2317C>A p.Q773K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.053); called by muse, mutect2
- THNSL1 | c.681C>A p.D227E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2
- DIPK1B | c.354C>A p.G118= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- FLACC1 | c.1248A>G p.E416= | Silent (SNP) | VAF 58/123 reads (47%) | called by muse, mutect2, varscan2
- HMMR | c.24G>A p.L8= | Silent (SNP) | VAF 60/138 reads (43%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.-217-535G>T | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- ELL3 | c.-27G>T | 5'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- POU2F2 | c.1198+10G>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- TMCO3 | c.624+10C>A | Intron (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
